Somatic mutation profile of tumor specimen ALCH-AENC-TTR1-A (aliquot ALCH-AENC-TTR1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-AENC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,173 days).
Specimen ALCH-AENC-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d268e766-ab29-41cf-ad2b-52a7f3f6f639.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AENC-NB1-A (Blood Derived Normal), aliquot ALCH-AENC-NB1-A-1-0-D-A667-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c6dfc29-5cae-4564-b613-1bb1907a25d3

The open-access MAF lists 544 somatic variants for this specimen: 379 protein-altering or splice-affecting, 96 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 96, Intron 38, Nonsense Mutation 20, Frame Shift Del 18, RNA 14, Splice Site 12, 5'UTR 8, 3'UTR 6, Frame Shift Ins 4, 5'Flank 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 61/78 reads (78%) | catalogued as rs886043247, CM030506, COSV57295964, COSV99927064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>T p.X187_splice | Splice Site (SNP) | VAF 112/129 reads (87%) | hotspot (GDC flag); catalogued as CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; called by muse, mutect2, varscan2
- ABCA13 | c.762C>G p.T254= | Splice Region (SNP) | VAF 47/129 reads (36%) | catalogued as COSV70047850; called by muse, mutect2, varscan2
- ACACB | c.3610T>G p.S1204A | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1356312009; called by muse, mutect2, varscan2
- ADCY5 | c.502C>A p.R168S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as rs1334092186; called by muse, mutect2, varscan2
- ADD3 | c.754C>G p.Q252E | Missense Mutation (SNP) | VAF 81/94 reads (86%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.81); catalogued as COSV53324513; called by muse, mutect2, varscan2
- AK9 | c.5086G>A p.A1696T | Missense Mutation (SNP) | VAF 130/230 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69853366, COSV69853872; called by muse, mutect2, varscan2
- ALX1 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV57491034; called by muse, mutect2, varscan2
- AMOTL1 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58567849; called by muse, mutect2
- ARHGAP15 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV54497846; called by mutect2, varscan2
- ARHGAP28 | c.790C>T p.P264S (on ENST00000383472 / NM_001366230.1; = p.P105S on NM_001010000.3) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs191955313; called by muse, mutect2, varscan2
- ASCC3 | c.3745G>T p.E1249* | Nonsense Mutation (SNP) | VAF 86/250 reads (34%) | catalogued as COSV100226391; called by muse, mutect2, varscan2
- ATXN2L | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1275001677; called by muse, mutect2, varscan2
- AZIN2 | c.380A>T p.H127L | Missense Mutation (SNP) | VAF 62/470 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1036712762; called by muse, mutect2, varscan2
- BMPR2 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 141/272 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV65810927; called by muse, mutect2, varscan2
- BSND | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV64870710; called by muse, mutect2, varscan2
- C12orf40 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 108/212 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100210165; called by muse, mutect2, varscan2
- C6orf201 | c.383-2A>G p.X128_splice | Splice Site (SNP) | VAF 198/353 reads (56%) | catalogued as COSV60986212; called by muse, mutect2, varscan2
- CCDC136 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1238402715; called by muse, mutect2
- CDH18 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs755751776; called by muse, mutect2
- CLSTN2 | c.2575C>A p.H859N | Missense Mutation (SNP) | VAF 182/359 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV71721550; called by muse, mutect2, varscan2
- COL24A1 | c.3710G>A p.G1237D | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159499147; called by muse, mutect2, varscan2
- CXorf21 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.09); catalogued as COSV66762357, COSV66762998; called by muse, mutect2, varscan2
- DLX3 | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 96/162 reads (59%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.777); catalogued as COSV101460515; called by muse, mutect2, varscan2
- DNAH7 | c.10217G>T p.G3406V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs906169840, COSV56759131; called by muse, mutect2, varscan2
- DPPA4 | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 167/320 reads (52%) | catalogued as COSV59509371; called by muse, mutect2, varscan2
- ERRFI1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 48/614 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.307); catalogued as COSV101088117; called by muse, mutect2
- ETV3L | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 58/125 reads (46%) | catalogued as COSV71901024; called by muse, mutect2, varscan2
- EVC2 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 87/168 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs776830520, COSV100186115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI5 | c.2432G>T p.*811Lext*4 | Nonstop Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100945469; called by muse, mutect2, varscan2
- FAM104A | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs765855105; called by muse, mutect2, varscan2
- FAM71B | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 120/144 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV100262204; called by muse, mutect2, varscan2
- FAT2 | c.4106G>T p.G1369V | Missense Mutation (SNP) | VAF 167/182 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759936860, COSV99944595; called by muse, mutect2, varscan2
- FH | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs981562354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHL1 | c.908T>A p.V303E (on ENST00000651089 / NM_001369326.1; = p.S236R on NM_001449.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV61783207; called by muse, varscan2
- FLT4 | c.2571del p.K858Rfs*21 | Frame Shift Del (DEL) | VAF 50/118 reads (42%) | catalogued as COSV56115975; called by mutect2, pindel, varscan2
- FNDC1 | c.3518A>G p.Q1173R | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs375160477; called by muse, mutect2, varscan2
- FOXF2 | c.919_920insGCA p.D307delinsGN | In Frame Ins (INS) | VAF 21/43 reads (49%) | catalogued as COSV52525393; called by mutect2, pindel, varscan2
- FOXP3 | c.1241G>C p.R414P | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66051211; called by muse, mutect2, varscan2
- GABPB2 | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100927192; called by muse, mutect2, varscan2
- GRIK3 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV100902388; called by muse, mutect2
- GRIK4 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as COSV101483516; called by muse, mutect2, varscan2
- GTPBP2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs768182541; called by muse, mutect2, varscan2
- HSPB7 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs765611158; called by muse, mutect2, varscan2
- IGF2R | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs371916370; called by muse, mutect2, varscan2
- IGSF22 | c.2215C>G p.R739G (on ENST00000319338; = p.R840G on NM_173588.4) | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV60038196; called by muse, mutect2, varscan2
- ILKAP | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104392794; called by muse, mutect2
- ITGA8 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 170/189 reads (90%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV100959555; called by muse, mutect2, varscan2
- ITM2A | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 143/247 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1266440922; called by muse, mutect2, varscan2
- JHY | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs139995595, COSV57078751; called by muse, mutect2, varscan2
- KANSL2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs775015748; called by muse, mutect2, varscan2
- KCNK16 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.244); catalogued as rs764549881, COSV64677446; called by muse, mutect2
- KDR | c.877A>G p.T293A | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs548382655; called by muse, mutect2, varscan2
- KRT81 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs201991772; called by muse, mutect2, varscan2
- LDB2 | c.259del p.R87Vfs*11 | Frame Shift Del (DEL) | VAF 38/120 reads (32%) | catalogued as COSV100453449, COSV100454251; called by mutect2, pindel, varscan2
- LFNG | c.1052C>T p.S351L (on ENST00000222725 / NM_001040167.2; = p.S222L on NM_002304.2) | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs763866787; called by muse, mutect2, varscan2
- LGI4 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1184063861; called by muse, mutect2, varscan2
- LILRA6 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 145/228 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54428700; called by muse, mutect2, varscan2
- LRRC7 | c.422-1G>A p.X141_splice (on ENST00000651989 / NM_001370785.2; = p.X108_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 111/165 reads (67%) | catalogued as COSV99224582; called by muse, mutect2, varscan2
- LTK | c.1252C>T p.L418= | Splice Region (SNP) | VAF 26/49 reads (53%) | catalogued as rs1473617912; called by muse, mutect2, varscan2
- MAGEE2 | c.1324C>A p.R442S | Missense Mutation (SNP) | VAF 103/291 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs781070212, COSV100973158; called by muse, mutect2, varscan2
- MAP2 | c.4150G>T p.D1384Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266392795; called by muse, mutect2
- MCOLN2 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 109/199 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99393560; called by muse, mutect2, varscan2
- MORC1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV99226655; called by muse, mutect2, varscan2
- MTRNR2L5 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 63/72 reads (88%) | PolyPhen benign (0); catalogued as rs766474179; called by muse, mutect2, varscan2
- MYH13 | c.5374C>A p.Q1792K | Missense Mutation (SNP) | VAF 131/146 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV99352856; called by muse, mutect2, varscan2
- NEXMIF | c.3694A>C p.I1232L | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99281031; called by muse, mutect2, varscan2
- NPBWR1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1286266756; called by muse, mutect2, varscan2
- NRDC | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 81/98 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs768282290; called by muse, mutect2, varscan2
- NTN4 | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 269/422 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760664968; called by muse, mutect2, varscan2
- NTNG2 | c.1139C>A p.T380K | Missense Mutation (SNP) | VAF 65/71 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62366326; called by muse, mutect2, varscan2
- NUAK1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs749623403; called by muse, mutect2, varscan2
- NUP210L | c.1739C>G p.A580G | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV55141735; called by muse, mutect2, varscan2
- NYX | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV61181802; called by muse, mutect2, varscan2
- OPRK1 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.927); catalogued as rs186551684; called by muse, mutect2, varscan2
- OR4B1 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 171/220 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV100535654; called by muse, mutect2, varscan2
- OR4P4 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100111668; called by muse, mutect2, varscan2
- OR51G2 | c.609C>G p.Y203* | Nonsense Mutation (SNP) | VAF 18/181 reads (10%) | catalogued as COSV58993216; called by muse, mutect2, varscan2
- OR51V1 | c.74A>C p.Q25P | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.222); catalogued as COSV58315096; called by muse, mutect2, varscan2
- OR8B12 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs761289895; called by muse, mutect2, varscan2
- OTOG | c.7075G>C p.V2359L | Missense Mutation (SNP) | VAF 64/90 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1189133443; called by muse, mutect2, varscan2
- PAG1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 66/254 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs775054099, COSV55058178; called by muse, mutect2, varscan2
- PCARE | c.1310G>T p.S437I | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs779690773; called by muse, mutect2, varscan2
- PDS5B | c.1354C>T p.R452* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV59734747; called by muse, varscan2
- PGLYRP3 | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV51951737; called by muse, mutect2, varscan2
- PJA1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779128771; called by muse, mutect2, varscan2
- PLEKHN1 | c.1945C>A p.Q649K (on ENST00000379409; = p.Q597K on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs866006704; called by muse, mutect2, varscan2
- PML | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 128/234 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs77069486; called by muse, mutect2, varscan2
- PPP4R2 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 103/140 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55594386; called by muse, mutect2, varscan2
- PRKD1 | c.1061G>T p.S354I | Missense Mutation (SNP) | VAF 399/647 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs1425147156; called by muse, mutect2, varscan2
- RAD17 | c.882T>G p.I294M (on ENST00000380774 / NM_133339.2; = p.I283M on NM_002873.1) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV104391770; called by muse, mutect2, varscan2
- RC3H2 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 142/170 reads (84%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV61798216; called by muse, mutect2, varscan2
- RIT2 | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 110/352 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1406264401; called by muse, mutect2, varscan2
- SCIN | c.769G>A p.A257T (on ENST00000297029 / NM_001112706.3; = p.A10T on NM_033128.3) | Missense Mutation (SNP) | VAF 180/285 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs763469468; called by muse, mutect2, varscan2
- SEL1L2 | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as COSV99533494; called by muse, mutect2, varscan2
- SLC8A3 | c.1889C>T p.A630V (on ENST00000381269 / NM_183002.3; = p.A631V on NM_033262.4) | Missense Mutation (SNP) | VAF 112/196 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs774149200, COSV53688951, COSV53692198; called by muse, mutect2, varscan2
- SLITRK2 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs782518844, COSV59429934; called by muse, mutect2, varscan2
- SMG1 | c.2384T>C p.L795S | Missense Mutation (SNP) | VAF 109/159 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV67173918; called by muse, mutect2, varscan2
- SMG1 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 142/539 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765587087, COSV67169826; called by muse, mutect2, varscan2
- SPHKAP | c.3225del p.W1075* | Frame Shift Del (DEL) | VAF 52/121 reads (43%) | catalogued as COSV60879794; called by mutect2, pindel, varscan2
- SPRED2 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 60/71 reads (85%) | catalogued as COSV62695227; called by muse, mutect2, varscan2
- SYNE1 | c.21657-1G>T p.X7219_splice (on ENST00000367255 / NM_182961.4; = p.X7148_splice on NM_033071.3) | Splice Site (SNP) | VAF 86/286 reads (30%) | catalogued as COSV54955112; called by muse, mutect2, varscan2
- SYT13 | c.410-1G>T p.X137_splice | Splice Site (SNP) | VAF 10/68 reads (15%) | catalogued as COSV50073894; called by muse, mutect2, varscan2
- TCEAL2 | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61197766; called by muse, mutect2, varscan2
- TENM2 | c.5633G>A p.R1878H (on ENST00000518659 / NM_001122679.2; = p.R1639H on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs754293472; called by muse, mutect2, varscan2
- TIAM1 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs1462610021, COSV54555018; called by muse, mutect2, varscan2
- TMEM19 | c.881G>T p.S294I | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as COSV56999893; called by muse, mutect2, varscan2
- TNNT1 | c.7G>C p.D3H | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.407); catalogued as COSV52571698; called by muse, mutect2, varscan2
- TRIT1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 57/502 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs866540220; called by muse, mutect2, varscan2
- TTN | c.62911G>A p.D20971N (on ENST00000591111; = p.D13547N on NM_003319.4) | Missense Mutation (SNP) | VAF 58/230 reads (25%) | PolyPhen probably damaging (0.998); catalogued as rs757888367, COSV60313118; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UBE2J2 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs928340026, COSV59572156; called by muse, mutect2, varscan2
- UGT1A9 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 156/285 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100693099; called by muse, mutect2, varscan2
- UNC80 | c.1283G>C p.R428T | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV99779486; called by muse, mutect2, varscan2
- XPO6 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs774960516, COSV100484740; called by muse, mutect2, varscan2
- ZFAT | c.2795G>A p.S932N | Missense Mutation (SNP) | VAF 123/388 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as COSV100914852; called by muse, mutect2, varscan2
- ZFHX4 | c.5322G>T p.L1774F | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99269900; called by muse, mutect2, varscan2
- ZNF114 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59944191; called by muse, mutect2, varscan2
- ZNF367 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 103/118 reads (87%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100930878; called by muse, mutect2, varscan2
- ZNF532 | c.3776G>A p.G1259D | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs1486486746; called by muse, mutect2, varscan2
- ZNF536 | c.1630C>A p.L544M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV62834710; called by muse, mutect2, varscan2
- ZNF646 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV56212427; called by muse, mutect2, varscan2
- ZNF665 | c.899G>A p.R300Q (on ENST00000600412; = p.R365Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs754537311, COSV101128668; called by muse, mutect2, varscan2
- ZNF69 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 76/116 reads (66%) | SIFT tolerated (0.78); PolyPhen benign (0.163); catalogued as rs750082012; called by muse, mutect2, varscan2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ZNF85 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs879001677; called by muse, mutect2, varscan2
- ZSCAN4 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99989692; called by muse, mutect2, varscan2
- ABCB1 | c.2730G>T p.L910F | Missense Mutation (SNP) | VAF 271/518 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB11 | c.3554T>C p.M1185T | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABCC12 | c.2858T>C p.L953S | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- ABCD1 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC092143.1 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ACSF3 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ADAM23 | c.553G>T p.G185W | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS16 | c.5A>T p.K2M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1955G>T p.R652L | Missense Mutation (SNP) | VAF 101/126 reads (80%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ADCY7 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ADGRG4 | c.1513C>A p.H505N | Missense Mutation (SNP) | VAF 101/334 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ALK | c.1949C>G p.P650R | Missense Mutation (SNP) | VAF 161/566 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ALMS1 | c.7052G>T p.W2351L | Missense Mutation (SNP) | VAF 137/170 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD49 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- APOB | c.5386A>T p.T1796S | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARX | c.1534G>T p.V512L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ATP8A1 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- ATXN1L | c.100A>G p.T34A | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BBX | c.906+1G>T p.X302_splice | Splice Site (SNP) | VAF 174/277 reads (63%) | called by muse, varscan2
- BEND5 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- BRDT | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 121/173 reads (70%) | SIFT tolerated (0.34); PolyPhen benign (0.071); called by muse, varscan2
- BRSK2 | c.1756C>A p.P586T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- BTNL2 | c.770T>C p.V257A | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.45); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- BTNL3 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 73/210 reads (35%) | called by muse, mutect2, varscan2
- BTNL3 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 58/141 reads (41%) | called by muse, mutect2, varscan2
- C12orf40 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 205/402 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CACNA1C | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA1F | c.4310T>A p.V1437E | Missense Mutation (SNP) | VAF 128/349 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACTIN | c.2152G>T p.D718Y | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS2 | c.3074A>T p.D1025V | Missense Mutation (SNP) | VAF 89/161 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAMTA1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 38/1210 reads (3%) | called by muse, mutect2
- CASK | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBX2 | c.859G>T p.G287W | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CCDC120 | c.1821G>T p.Q607H | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- CCDC149 | c.157T>A p.Y53N | Missense Mutation (SNP) | VAF 94/177 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC181 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD8A | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 160/172 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CDH13 | c.1082C>G p.P361R | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFAP47 | c.7217G>T p.G2406V | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CIP2A | c.1635-1G>C p.X545_splice | Splice Site (SNP) | VAF 42/109 reads (39%) | called by muse, mutect2, varscan2
- CLCN1 | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 84/508 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CLDN4 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CLEC18B | c.524T>A p.I175K | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.079); called by muse, mutect2
- CLEC18C | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 131/226 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- COL12A1 | c.375del p.G126Efs*35 | Frame Shift Del (DEL) | VAF 134/299 reads (45%) | called by mutect2, pindel, varscan2
- COL1A2 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 274/495 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- COL4A5 | c.3559C>A p.P1187T | Missense Mutation (SNP) | VAF 182/589 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CP | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 184/351 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CPE | c.367C>A p.L123M | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAGLA | c.1140del p.F382Sfs*13 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- DARS1 | c.359_360del p.V120Efs*16 | Frame Shift Del (DEL) | VAF 19/102 reads (19%) | called by pindel, varscan2
- DCHS1 | c.8399C>A p.S2800* | Nonsense Mutation (SNP) | VAF 84/120 reads (70%) | called by muse, mutect2, varscan2
- DCP1A | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 156/354 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DENND2A | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- DIPK2B | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMD | c.4904G>T p.G1635V | Missense Mutation (SNP) | VAF 210/576 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DMD | c.4903G>C p.G1635R | Missense Mutation (SNP) | VAF 200/564 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DMD | c.2855G>T p.R952M | Missense Mutation (SNP) | VAF 181/502 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH11 | c.2467T>A p.L823M | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 66/81 reads (81%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH9 | c.12203G>T p.G4068V | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAJC13 | c.6070C>G p.L2024V | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.84); called by muse, varscan2
- DOK4 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 90/138 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- DPH1 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- DPP10 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP6 | c.1561G>A p.G521S (on ENST00000377770 / NM_001364500.2; = p.G459S on NM_001936.5) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- DSG2 | c.1487G>T p.C496F | Missense Mutation (SNP) | VAF 161/341 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DTNB | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 126/217 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC1I1 | c.437A>G p.H146R | Missense Mutation (SNP) | VAF 152/246 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYRK1A | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 172/422 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EEF1D | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- EFTUD2 | c.397A>T p.T133S | Missense Mutation (SNP) | VAF 36/429 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- ENAH | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 109/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP2 | c.2444G>T p.W815L (on ENST00000075322 / NM_001040092.3; = p.W867L on NM_006209.5) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L2 | c.2495G>A p.G832D | Missense Mutation (SNP) | VAF 163/342 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- ESPL1 | c.6251G>C p.G2084A | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ESYT2 | c.812+1G>T p.X271_splice (on ENST00000613624; = p.X195_splice on NM_020728.3) | Splice Site (SNP) | VAF 110/384 reads (29%) | called by muse, mutect2, varscan2
- EZHIP | c.310C>G p.R104G | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAAP100 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FAT2 | c.4105G>T p.G1369W | Missense Mutation (SNP) | VAF 170/186 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG2 | c.4327C>A p.Q1443K | Missense Mutation (SNP) | VAF 255/571 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNA | c.7402G>T p.G2468C (on ENST00000369850 / NM_001110556.2; = p.G2460C on NM_001456.3) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT1 | c.916A>C p.K306Q | Missense Mutation (SNP) | VAF 172/324 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FOLR3 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FOXD4L6 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- FOXP2 | c.1507G>C p.V503L | Missense Mutation (SNP) | VAF 155/512 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- FOXP3 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- FREM3 | c.3863A>T p.K1288M | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- FRG2C | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 74/636 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD6 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 121/447 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- GAB4 | c.1105C>A p.L369M | Missense Mutation (SNP) | VAF 73/122 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GABBR1 | c.1425G>T p.W475C | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- GAREM1 | c.1101C>G p.H367Q | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GIPC1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- GOLGA6L22 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.1); called by muse, mutect2, varscan2
- GORASP2 | c.270G>T p.W90C | Missense Mutation (SNP) | VAF 171/295 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPA33 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GRIK1 | c.1145dup p.N382Kfs*8 | Frame Shift Ins (INS) | VAF 39/135 reads (29%) | called by mutect2, pindel, varscan2
- GUCY1B1 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.117); called by muse, mutect2
- HAPLN4 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCFC1 | c.3376A>T p.S1126C | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HFE | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HOXD9 | c.237G>C p.W79C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HS6ST1 | c.561del p.V188Cfs*5 | Frame Shift Del (DEL) | VAF 66/159 reads (42%) | called by pindel, varscan2
- HSFX2 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by mutect2, varscan2
- IFIH1 | c.2559G>T p.M853I | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGSF21 | c.1149_1150del p.S383Rfs*8 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- IKBKG | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); called by mutect2, varscan2
- IP6K3 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ISL2 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | called by muse, mutect2, varscan2
- ISL2 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KALRN | c.8060T>C p.L2687P (on ENST00000360013 / NM_001024660.4; = p.L990P on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KCNA7 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- KCNH8 | c.2787T>G p.S929R | Missense Mutation (SNP) | VAF 236/264 reads (89%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KIAA0895 | c.166T>A p.F56I | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF26A | c.4000G>T p.G1334W | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- KIF4A | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 37/570 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KIR3DL1 | c.55del p.A19Pfs*27 | Frame Shift Del (DEL) | VAF 40/217 reads (18%) | called by mutect2, pindel, varscan2
- LAMA2 | c.4232G>T p.G1411V | Missense Mutation (SNP) | VAF 184/612 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LAMB2 | c.2265del p.S757Afs*35 | Frame Shift Del (DEL) | VAF 83/124 reads (67%) | called by mutect2, pindel, varscan2
- LGI2 | c.1479T>A p.D493E | Missense Mutation (SNP) | VAF 114/196 reads (58%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- LHX5 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- LHX8 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 92/120 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LMO4 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 63/278 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- LRRIQ1 | c.4638-1G>C p.X1546_splice | Splice Site (SNP) | VAF 116/181 reads (64%) | called by muse, mutect2, varscan2
- MACF1 | c.2742G>T p.M914I | Missense Mutation (SNP) | VAF 40/363 reads (11%) | called by muse, mutect2, varscan2
- MAF1 | c.509C>A p.P170Q | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAGEE2 | c.846_857del p.E283_N286del | In Frame Del (DEL) | VAF 185/381 reads (49%) | called by mutect2, pindel, varscan2
- MAPK9 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 81/582 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- MED12 | c.1590G>T p.E530D | Missense Mutation (SNP) | VAF 295/509 reads (58%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- MED12 | c.3980C>T p.P1327L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED14 | c.4064C>A p.P1355H | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- METTL27 | c.502del p.R168Gfs*76 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- MSGN1 | c.378G>T p.R126S | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2
- MTHFR | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MUC19 | c.922A>G p.S308G | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- MYF5 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 80/126 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MYH15 | c.4317C>G p.D1439E | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); called by muse, mutect2
- MYLK | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 226/360 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- NAP1L2 | c.953A>G p.H318R | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- NCKAP1L | c.2680del p.L894Cfs*5 | Frame Shift Del (DEL) | VAF 69/330 reads (21%) | called by mutect2, pindel, varscan2
- NELL1 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 112/169 reads (66%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NHS | c.3695C>A p.T1232K | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKD1 | c.259+1G>A p.X87_splice | Splice Site (SNP) | VAF 92/174 reads (53%) | called by muse, mutect2, varscan2
- NRCAM | c.1786G>T p.V596F (on ENST00000379028 / NM_001371124.1; = p.V590F on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/124 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OBSCN | c.17689A>T p.I5897F | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- OPCML | c.1015G>C p.A339P | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- OPN1LW | c.298C>G p.L100V | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2
- OR10AG1 | c.662C>A p.S221* | Nonsense Mutation (SNP) | VAF 20/165 reads (12%) | called by muse, mutect2, varscan2
- OR2B2 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2M4 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- OR4A47 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- OR4N2 | c.455del p.G152Vfs*47 | Frame Shift Del (DEL) | VAF 41/228 reads (18%) | called by mutect2, varscan2
- OR51B2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 105/151 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR56A5 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5B3 | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6S1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR9K2 | c.436G>T p.D146Y (on ENST00000305377; = p.D124Y on NM_001005243.1) | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1194G>T p.E398D (on ENST00000259318 / NM_001136562.3; = p.E629D on NM_007203.5) | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PASD1 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 157/356 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PCDHGB5 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 188/212 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDHB | c.445_447delinsTG p.G149Wfs*6 | Frame Shift Del (DEL) | VAF 76/103 reads (74%) | called by pindel, varscan2*
- PHF24 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- PJA1 | c.517C>A p.R173S | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLXNA3 | c.2887G>A p.G963S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNB3 | c.916_917delinsC p.G306Pfs*86 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by pindel, varscan2*
- PNPLA3 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- POTEH | c.196T>A p.C66S | Missense Mutation (SNP) | VAF 104/308 reads (34%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.021); called by muse, varscan2
- PPP1R3F | c.1038G>T p.M346I | Missense Mutation (SNP) | VAF 115/288 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE3 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRPF40A | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PRSS21 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMA4 | c.594T>G p.N198K | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTPRF | c.3138dup p.L1047Sfs*94 | Frame Shift Ins (INS) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- PTPRQ | c.3258T>G p.I1086M (on ENST00000616559; = p.I1044M on NM_001145026.2) | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- RAB39B | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAD50 | c.3427A>C p.I1143L | Missense Mutation (SNP) | VAF 227/249 reads (91%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- RAD54L | c.761A>T p.K254M | Missense Mutation (SNP) | VAF 57/510 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- RASL12 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- REP15 | c.88C>A p.H30N | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- RFWD3 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 159/283 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RFX4 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RGS4 | c.394T>A p.C132S | Missense Mutation (SNP) | VAF 83/153 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHEB | c.305A>T p.K102I | Missense Mutation (SNP) | VAF 67/116 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RHO | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RHOB | c.290A>T p.E97V | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RIMS2 | c.4048C>T p.Q1350* | Nonsense Mutation (SNP) | VAF 78/137 reads (57%) | called by muse, mutect2, varscan2
- RNF123 | c.3364G>C p.V1122L | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ROBO4 | c.1712G>A p.G571D | Missense Mutation (SNP) | VAF 80/101 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.3866A>G p.D1289G | Missense Mutation (SNP) | VAF 353/785 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RYR2 | c.862C>A p.H288N | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RYR2 | c.13773C>A p.Y4591* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | called by mutect2, varscan2
- S100PBP | c.932_933insT p.T312Dfs*29 | Frame Shift Ins (INS) | VAF 291/460 reads (63%) | called by mutect2, pindel, varscan2
- SAGE1 | c.1559C>A p.P520Q | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SALL4 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 97/105 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SAMD9L | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 219/352 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF4 | c.2967G>T p.Q989H | Missense Mutation (SNP) | VAF 124/462 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); called by muse, varscan2
- SEMA6C | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD2 | c.7496_7504del p.I2499_T2501del | In Frame Del (DEL) | VAF 155/189 reads (82%) | called by mutect2, pindel, varscan2
- SEZ6 | c.2121T>A p.N707K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SFXN1 | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 102/109 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SHOC2 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 69/84 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SHROOM3 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SIM1 | c.586C>A p.L196M | Missense Mutation (SNP) | VAF 67/101 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- SLC7A13 | c.314C>A p.S105* | Nonsense Mutation (SNP) | VAF 92/194 reads (47%) | called by muse, mutect2, varscan2
- SLIT3 | c.4309G>T p.G1437C | Missense Mutation (SNP) | VAF 122/229 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLITRK4 | c.1486G>C p.A496P | Missense Mutation (SNP) | VAF 152/622 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SMC6 | c.1208G>C p.R403P | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SNTG1 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.824); called by muse, varscan2
- SPATA20 | c.2212dup p.D738Gfs*29 (on ENST00000356488 / NM_001258372.1; = p.D754Gfs*29 on NM_022827.4) | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel
- SPN | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 73/111 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STX18 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SUPT20H | c.853A>G p.K285E (on ENST00000350612 / NM_001014286.3; = p.K286E on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SWT1 | c.1205A>T p.K402I | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- TAF1L | c.1813G>A p.G605R | Missense Mutation (SNP) | VAF 88/105 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TAF9B | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TAOK2 | c.2622del p.K875Rfs*21 | Frame Shift Del (DEL) | VAF 24/151 reads (16%) | called by mutect2, pindel, varscan2
- TAS1R1 | c.723C>G p.F241L | Missense Mutation (SNP) | VAF 169/210 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TBC1D17 | c.1747-2A>T p.X583_splice | Splice Site (SNP) | VAF 74/111 reads (67%) | called by muse, mutect2, varscan2
- TBR1 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TECPR1 | c.3230A>T p.N1077I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX11 | c.1499T>A p.I500N (on ENST00000344304; = p.I485N on NM_031276.3) | Missense Mutation (SNP) | VAF 140/244 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TEX13C | c.1549C>G p.P517A | Missense Mutation (SNP) | VAF 109/181 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TEX55 | c.1472T>G p.I491R | Missense Mutation (SNP) | VAF 108/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- TIPIN | c.184A>G p.R62G | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TNIK | c.3169+1G>A p.X1057_splice | Splice Site (SNP) | VAF 102/189 reads (54%) | called by muse, mutect2
- TNIP2 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TNN | c.685A>G p.S229G | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- TRIM58 | c.77del p.P26Rfs*78 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- TRIP10 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TRIP12 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TTN | c.94588T>A p.Y31530N (on ENST00000591111; = p.Y24106N on NM_003319.4) | Missense Mutation (SNP) | VAF 136/230 reads (59%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.84403G>T p.G28135* (on ENST00000591111; = p.G20711* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/130 reads (14%) | called by muse, varscan2
- USP27X | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- VCAM1 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- VHLL | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- VPS50 | c.2722A>G p.K908E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR11 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 85/263 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- WDR45 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- WDR62 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR87 | c.1306G>T p.G436* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- ZBTB7B | c.434G>T p.G145V (on ENST00000292176; = p.G179V on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZIC3 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF143 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF292 | c.6575A>G p.H2192R | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF439 | c.1235G>T p.C412F | Missense Mutation (SNP) | VAF 124/197 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF549 | c.1088_1089del p.C363Yfs*12 (on ENST00000376233 / NM_001199295.2; = p.C350Yfs*12 on NM_153263.2) | Frame Shift Del (DEL) | VAF 66/177 reads (37%) | called by pindel, varscan2
- ZNF568 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF626 | c.62T>A p.L21Q | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF630 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZNF724 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZNF775 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZSCAN9 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 64/108 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ABCA13 | c.13401C>T p.S4467= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as rs757057171; called by muse, mutect2, varscan2
- ABCA6 | c.2940T>C p.I980= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs750063702, COSV52638392; called by muse, mutect2, varscan2
- AC006059.2 | c.2001C>G p.S667= | Silent (SNP) | VAF 92/108 reads (85%) | called by muse, mutect2, varscan2
- ADGRF5 | c.2058A>G p.L686= | Silent (SNP) | VAF 186/498 reads (37%) | called by muse, mutect2, varscan2
- ADGRG7 | c.153C>T p.F51= | Silent (SNP) | VAF 59/352 reads (17%) | catalogued as COSV99841417; called by muse, mutect2, varscan2
- AKAP4 | c.2103A>C p.V701= | Silent (SNP) | VAF 147/327 reads (45%) | called by muse, mutect2, varscan2
- AMOTL1 | c.2034G>T p.L678= | Silent (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- APOBEC3F | c.552A>G p.L184= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs149410972; called by muse, mutect2, varscan2
- ATP2A2 | c.1497A>G p.T499= | Silent (SNP) | VAF 351/625 reads (56%) | called by muse, mutect2, varscan2
- CA5B | c.270C>A p.A90= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2, varscan2
- CCDC175 | c.978A>G p.E326= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- CDH8 | c.426G>A p.E142= | Silent (SNP) | VAF 114/430 reads (27%) | called by muse, mutect2, varscan2
- CDH9 | c.657T>C p.T219= | Silent (SNP) | VAF 121/239 reads (51%) | catalogued as rs771433767, COSV99142424; called by muse, mutect2, varscan2
- CNGA2 | c.1194C>T p.F398= | Silent (SNP) | VAF 119/360 reads (33%) | catalogued as rs1351027080, COSV61703840; called by muse, mutect2, varscan2
- CNGB3 | c.2223T>C p.D741= | Silent (SNP) | VAF 33/319 reads (10%) | catalogued as rs774113227; called by muse, mutect2, varscan2
- COL6A6 | c.3636C>A p.T1212= | Silent (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- CX3CL1 | c.987T>A p.T329= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- CYP11B2 | c.228G>T p.G76= | Silent (SNP) | VAF 97/183 reads (53%) | called by muse, mutect2, varscan2
- DCAF11 | c.354G>A p.G118= | Silent (SNP) | VAF 171/256 reads (67%) | called by muse, mutect2, varscan2
- DENND2A | c.2052G>T p.V684= | Silent (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- DIP2A | c.3735C>T p.F1245= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV100595779; called by muse, mutect2, varscan2
- DMTF1 | c.981C>T p.N327= | Silent (SNP) | VAF 136/457 reads (30%) | called by muse, mutect2, varscan2
- DRP2 | c.2130G>C p.P710= | Silent (SNP) | VAF 64/220 reads (29%) | catalogued as COSV65810285; called by muse, mutect2, varscan2
- EMX2 | c.156C>T p.H52= | Silent (SNP) | VAF 69/79 reads (87%) | catalogued as COSV71294776; called by muse, mutect2, varscan2
- EPB42 | c.1434C>A p.L478= (on ENST00000441366 / NM_001114134.2; = p.L508= on NM_000119.3) | Silent (SNP) | VAF 90/172 reads (52%) | called by muse, mutect2, varscan2
- EVC | c.1389G>T p.T463= | Silent (SNP) | VAF 72/200 reads (36%) | catalogued as COSV53829283, COSV53834148; called by mutect2, varscan2
- EXOC6 | c.1236A>T p.R412= | Silent (SNP) | VAF 146/159 reads (92%) | called by muse, mutect2, varscan2
- EXPH5 | c.5214C>A p.T1738= | Silent (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
- FAM111B | c.1173T>C p.Y391= | Silent (SNP) | VAF 96/130 reads (74%) | catalogued as rs1412384177; called by muse, mutect2, varscan2
- GATA6 | c.42C>T p.F14= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- GMPS | c.1341A>C p.V447= | Silent (SNP) | VAF 217/464 reads (47%) | called by muse, mutect2, varscan2
- GPLD1 | c.1386C>T p.D462= | Silent (SNP) | VAF 46/144 reads (32%) | catalogued as rs1062506, COSV100015424; called by muse, mutect2, varscan2
- GUCY2C | c.1806A>T p.S602= | Silent (SNP) | VAF 136/223 reads (61%) | called by muse, mutect2, varscan2
- HRNR | c.8514T>C p.Y2838= | Silent (SNP) | VAF 34/156 reads (22%) | catalogued as COSV64258045; called by muse, varscan2
- IDS | c.396G>T p.S132= | Silent (SNP) | VAF 78/318 reads (25%) | catalogued as COSV100557903; called by muse, mutect2, varscan2
- IGHE | c.135A>T p.T45= | Silent (SNP) | VAF 63/259 reads (24%) | called by muse, mutect2, varscan2
- IMPA2 | c.468G>T p.R156= | Silent (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- ITM2C | c.111G>T p.T37= | Silent (SNP) | VAF 16/21 reads (76%) | called by muse, mutect2, varscan2
- ITSN2 | c.5034C>T p.P1678= | Silent (SNP) | VAF 50/193 reads (26%) | catalogued as rs149080724; called by muse, mutect2, varscan2
- KCNJ1 | c.246C>T p.T82= | Silent (SNP) | VAF 79/109 reads (72%) | called by muse, mutect2, varscan2
- KIF19 | c.1062C>G p.L354= | Silent (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.258G>T p.V86= (on ENST00000396284; = p.V47= on NM_001080770.2) | Silent (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- KRT79 | c.42G>A p.G14= | Silent (SNP) | VAF 140/232 reads (60%) | called by muse, mutect2, varscan2
- KRTAP10-7 | c.723C>T p.P241= | Silent (SNP) | VAF 77/167 reads (46%) | catalogued as rs587638590; called by muse, mutect2, varscan2
- LRPAP1 | c.57G>T p.L19= | Silent (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- MAD1L1 | c.1839G>C p.L613= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV56235998; called by muse, mutect2, varscan2
- MAGEB3 | c.498T>A p.V166= | Silent (SNP) | VAF 104/318 reads (33%) | called by muse, mutect2, varscan2
- MCOLN1 | c.1482C>T p.S494= | Silent (SNP) | VAF 72/300 reads (24%) | called by muse, mutect2, varscan2
- MEGF10 | c.204A>G p.K68= | Silent (SNP) | VAF 64/149 reads (43%) | called by muse, mutect2, varscan2
- MYCBP2 | c.13155C>T p.D4385= (on ENST00000357337; = p.D4423= on NM_015057.5) | Silent (SNP) | VAF 44/191 reads (23%) | catalogued as rs756368403; called by muse, mutect2, varscan2
- MYH6 | c.2985C>A p.T995= | Silent (SNP) | VAF 164/250 reads (66%) | catalogued as rs1392879222; called by muse, mutect2, varscan2
- MYH8 | c.4788C>A p.V1596= | Silent (SNP) | VAF 224/250 reads (90%) | catalogued as COSV67970973; called by muse, mutect2, varscan2
- NCDN | c.1812A>T p.S604= | Silent (SNP) | VAF 111/136 reads (82%) | called by muse, mutect2, varscan2
- NFS1 | c.909G>T p.G303= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as rs1332409380, COSV65053792; called by muse, mutect2, varscan2
- NID2 | c.1614C>A p.G538= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV99356282; called by muse, mutect2, varscan2
- NLRP11 | c.807A>T p.P269= | Silent (SNP) | VAF 130/204 reads (64%) | called by muse, mutect2, varscan2
- NPY1R | c.921C>A p.L307= | Silent (SNP) | VAF 53/133 reads (40%) | called by muse, mutect2, varscan2
- NXPH1 | c.234C>A p.T78= | Silent (SNP) | VAF 55/167 reads (33%) | catalogued as rs778080583; called by muse, mutect2, varscan2
- OR11H12 | c.30C>A p.G10= | Silent (SNP) | VAF 213/485 reads (44%) | catalogued as COSV101612494; called by muse, mutect2, varscan2
- OR4C16 | c.102G>A p.L34= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as COSV58943901; called by muse, mutect2, varscan2
- OR52I2 | c.501G>C p.T167= | Silent (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- OR5AN1 | c.903C>T p.A301= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- OR6B3 | c.837A>G p.T279= | Silent (SNP) | VAF 64/196 reads (33%) | called by muse, mutect2, varscan2
- OTOP2 | c.309C>T p.L103= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1439956024; called by muse, mutect2, varscan2
- PCDH11X | c.2202A>G p.T734= | Silent (SNP) | VAF 106/345 reads (31%) | catalogued as rs1166653890; called by muse, mutect2, varscan2
- PCDHA1 | c.1578G>A p.E526= | Silent (SNP) | VAF 212/237 reads (89%) | called by muse, mutect2, varscan2
- PCDHB1 | c.1242G>A p.E414= | Silent (SNP) | VAF 175/187 reads (94%) | catalogued as rs782270613; called by muse, mutect2, varscan2
- PEPD | c.72C>T p.A24= | Silent (SNP) | VAF 96/154 reads (62%) | called by muse, mutect2, varscan2
- PKN1 | c.1587A>C p.T529= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- POLA2 | c.15C>T p.A5= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as rs896276038; called by muse, mutect2, varscan2
- PTPRZ1 | c.2859T>C p.S953= | Silent (SNP) | VAF 84/278 reads (30%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.2668C>T p.L890= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- SCN5A | c.5244C>T p.G1748= (on ENST00000333535 / NM_198056.3; = p.G1747= on NM_000335.5) | Silent (SNP) | VAF 132/150 reads (88%) | called by muse, mutect2, varscan2
- SCN9A | c.2055C>A p.L685= (on ENST00000303354; = p.L674= on NM_002977.3) | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as COSV100313101; called by muse, mutect2, varscan2
- SEMA6C | c.576G>T p.A192= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100501667; called by muse, mutect2, varscan2
- SIM2 | c.423G>T p.T141= | Silent (SNP) | VAF 88/206 reads (43%) | catalogued as rs138136486; called by muse, mutect2, varscan2
- SLC10A3 | c.177A>T p.P59= | Silent (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- SLC35D3 | c.774G>A p.V258= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- SLC9A3 | c.1411C>A p.R471= | Silent (SNP) | VAF 74/195 reads (38%) | called by muse, mutect2, varscan2
- STAG1 | c.3306T>C p.T1102= | Silent (SNP) | VAF 51/77 reads (66%) | called by muse, mutect2, varscan2
- STK10 | c.426A>G p.L142= | Silent (SNP) | VAF 130/269 reads (48%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.702G>T p.P234= | Silent (SNP) | VAF 93/274 reads (34%) | called by muse, mutect2, varscan2
- SYNE2 | c.18825A>G p.S6275= | Silent (SNP) | VAF 115/554 reads (21%) | called by muse, mutect2, varscan2
- TEX55 | c.1470T>C p.S490= | Silent (SNP) | VAF 102/350 reads (29%) | called by muse, mutect2
- TRIM51GP | c.321C>T p.D107= | Silent (SNP) | VAF 25/240 reads (10%) | catalogued as rs745582380; called by muse, mutect2, varscan2
- TRPV3 | c.1143G>A p.A381= | Silent (SNP) | VAF 50/90 reads (56%) | catalogued as rs141437962; called by muse, mutect2, varscan2
- TTN | c.44742T>A p.P14914= (on ENST00000591111; = p.P7490= on NM_003319.4) | Silent (SNP) | VAF 94/332 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.20553C>G p.V6851= (on ENST00000591111; = p.V5924= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/134 reads (32%) | called by muse, mutect2, varscan2
- UBR4 | c.13143G>A p.P4381= | Silent (SNP) | VAF 88/280 reads (31%) | catalogued as rs111323489; called by muse, mutect2, varscan2
- UGT1A10 | c.63C>T p.G21= | Silent (SNP) | VAF 80/135 reads (59%) | catalogued as rs776178940; called by muse, mutect2, varscan2
- UPRT | c.78C>T p.P26= | Silent (SNP) | VAF 34/108 reads (31%) | called by muse, varscan2
- UPRT | c.231G>A p.E77= | Silent (SNP) | VAF 45/128 reads (35%) | called by muse, varscan2
- VASP | c.804C>T p.N268= | Silent (SNP) | VAF 17/153 reads (11%) | catalogued as rs746004105; called by muse, mutect2, varscan2
- VBP1 | c.579C>G p.T193= | Silent (SNP) | VAF 88/367 reads (24%) | catalogued as COSV99660763; called by muse, mutect2, varscan2
- ZNF521 | c.3238C>T p.L1080= | Silent (SNP) | VAF 78/135 reads (58%) | catalogued as COSV64122948, COSV64127674; called by muse, mutect2, varscan2
- ZNF658 | c.267G>T p.G89= | Silent (SNP) | VAF 122/158 reads (77%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5512C>A | RNA (SNP) | VAF 62/93 reads (67%) | called by muse, mutect2, varscan2
- AC068643.2 | n.593+3663A>T | Intron (SNP) | VAF 161/242 reads (67%) | called by muse, mutect2, varscan2
- AC104078.1 | n.227C>G | RNA (SNP) | VAF 94/263 reads (36%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6288C>T | Intron (SNP) | VAF 172/286 reads (60%) | catalogued as rs764606429; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40444135 C>A | 5'Flank (SNP) | VAF 120/412 reads (29%) | called by muse, mutect2, varscan2
- ALG2 | c.*364T>G | 3'UTR (SNP) | VAF 108/261 reads (41%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.1993A>G | RNA (SNP) | VAF 201/325 reads (62%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498055 C>T | 5'Flank (SNP) | VAF 60/396 reads (15%) | catalogued as rs1184535371; called by mutect2, varscan2
- AP4M1 | c.-49G>A | 5'UTR (SNP) | VAF 69/117 reads (59%) | called by muse, mutect2, varscan2
- AVPR2 | chrX:153905055 A>G | 5'Flank (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- BLM | c.1088-148A>T | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- CACNA1G | c.-86G>T | 5'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- CARD8 | c.-20A>G | 5'UTR (SNP) | VAF 72/258 reads (28%) | catalogued as rs1035416358; called by muse, mutect2, varscan2
- CLASP1 | c.196-646_196-645insCTA | Intron (INS) | VAF 58/126 reads (46%) | called by mutect2, pindel, varscan2
- CLCN7 | c.1884-34G>T | Intron (SNP) | VAF 57/96 reads (59%) | called by muse, mutect2, varscan2
- CSTF2 | c.58+122G>T | Intron (SNP) | VAF 110/277 reads (40%) | catalogued as COSV63376406; called by muse, mutect2, varscan2
- CTNNB1 | c.1684-44A>G | Intron (SNP) | VAF 146/167 reads (87%) | called by muse, mutect2, varscan2
- DCDC1 | c.2715+8767T>C | Intron (SNP) | VAF 54/93 reads (58%) | called by muse, mutect2, varscan2
- DCHS2 | n.8062C>T | RNA (SNP) | VAF 70/147 reads (48%) | called by muse, mutect2, varscan2
- DHFR | c.-117dup | 5'UTR (INS) | VAF 14/19 reads (74%) | catalogued as rs754309248; called by mutect2, varscan2
- DHRS7 | c.972+124T>C | Intron (SNP) | VAF 10/54 reads (19%) | catalogued as rs748297796; called by muse, varscan2
- EPHB6 | c.1865+37A>G | Intron (SNP) | VAF 50/173 reads (29%) | called by muse, mutect2, varscan2
- FAM149A | c.1602+297A>G | Intron (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- FHL1 | c.*669C>A | 3'UTR (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- FLJ40194 | n.269C>G | RNA (SNP) | VAF 59/167 reads (35%) | called by muse, mutect2, varscan2
- GABRE | c.784+1218A>T | Intron (SNP) | VAF 146/431 reads (34%) | called by muse, mutect2, varscan2
- GNG5P2 | n.169A>G | RNA (SNP) | VAF 16/550 reads (3%) | called by muse, mutect2
- GNGT1 | c.-11-37C>A | Intron (SNP) | VAF 85/259 reads (33%) | catalogued as rs1320551612; called by muse, mutect2, varscan2
- HES4 | c.205-32G>T | Intron (SNP) | VAF 14/37 reads (38%) | catalogued as rs757783143; called by muse, mutect2, varscan2
- HSP90AA4P | n.1885G>T | RNA (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
- HYDIN | c.2075+398T>C | Intron (SNP) | VAF 115/442 reads (26%) | catalogued as rs1237144840; called by muse, mutect2, varscan2
- IVNS1ABP | c.657+498C>T | Intron (SNP) | VAF 94/241 reads (39%) | catalogued as rs1013790583, COSV62250104; called by muse, mutect2, varscan2
- LGALS4 | c.570+24G>T | Intron (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- LHX4 | c.248+19T>C | Intron (SNP) | VAF 115/291 reads (40%) | called by muse, mutect2, varscan2
- LINC02740 | n.210G>A | RNA (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- LMF1 | c.1530-1053G>T | Intron (SNP) | VAF 61/218 reads (28%) | called by muse, mutect2, varscan2
- MBD2 | c.702+1907C>T | Intron (SNP) | VAF 34/69 reads (49%) | catalogued as rs749547565; called by muse, mutect2, varscan2
- MDS2 | n.459G>C | RNA (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- MIB1 | c.1829+9291G>A | Intron (SNP) | VAF 20/39 reads (51%) | catalogued as rs1008614519; called by muse, mutect2, varscan2
- MRRFP1 | n.568C>A | RNA (SNP) | VAF 71/221 reads (32%) | called by muse, mutect2, varscan2
- MTMR1 | c.1656+188C>T | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as rs1557417584; called by muse, mutect2, varscan2
- NCBP2 | c.78+50A>G | Intron (SNP) | VAF 15/94 reads (16%) | catalogued as rs775997247; called by muse, mutect2, varscan2
- NCOA4 | c.-15+3043G>A | Intron (SNP) | VAF 239/257 reads (93%) | called by muse, mutect2, varscan2
- NUDT7 | c.190-405T>G | Intron (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1848G>A | Intron (SNP) | VAF 90/184 reads (49%) | catalogued as rs758570719, COSV52763535; called by muse, mutect2, varscan2
- ONECUT2 | c.1229-9242G>C | Intron (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- PBDC1 | c.-18G>C | 5'UTR (SNP) | VAF 48/161 reads (30%) | called by muse, mutect2, varscan2
- PDPK1 | c.1344-2947C>T | Intron (SNP) | VAF 120/188 reads (64%) | catalogued as rs1204200931; called by muse, mutect2, varscan2
- PIK3R6 | c.-179C>A | 5'UTR (SNP) | VAF 36/40 reads (90%) | catalogued as rs762918541; called by muse, mutect2, varscan2
- PLA2G6 | c.1348+851G>C | Intron (SNP) | VAF 39/75 reads (52%) | catalogued as COSV59269519; called by muse, mutect2, varscan2
- PLCG2 | c.*44G>A | 3'UTR (SNP) | VAF 101/211 reads (48%) | called by muse, mutect2, varscan2
- RBFOX3 | c.*4C>T | 3'UTR (SNP) | VAF 23/88 reads (26%) | catalogued as rs1284917244; called by muse, mutect2, varscan2
- RPGR | c.2520+88G>T | Intron (SNP) | VAF 155/472 reads (33%) | catalogued as COSV58840546; called by muse, mutect2, varscan2
- SCN1A | c.265-36A>G | Intron (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- SETD9 | c.-12C>A | 5'UTR (SNP) | VAF 53/60 reads (88%) | called by muse, mutect2, varscan2
- SGCD | c.-1+2319G>A | Intron (SNP) | VAF 95/114 reads (83%) | catalogued as rs752924735; called by muse, mutect2, varscan2
- SIRT2 | c.226+1539A>T | Intron (SNP) | VAF 85/153 reads (56%) | called by muse, mutect2, varscan2
- SP110 | c.1591-27C>T | Intron (SNP) | VAF 65/195 reads (33%) | catalogued as rs764475133; called by muse, mutect2, varscan2
- STAT3 | c.1234-28G>A | Intron (SNP) | VAF 248/426 reads (58%) | called by muse, mutect2, varscan2
- TF | c.1687+9A>G | Intron (SNP) | VAF 171/360 reads (48%) | called by muse, mutect2, varscan2
- TPRX2P | n.364G>T | RNA (SNP) | VAF 30/96 reads (31%) | called by muse, mutect2, varscan2
- TRIM53AP | n.405A>T | RNA (SNP) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- TYR | c.-8G>C | 5'UTR (SNP) | VAF 108/206 reads (52%) | called by muse, mutect2, varscan2
- UGT2B27P | n.876T>C | RNA (SNP) | VAF 142/316 reads (45%) | called by muse, varscan2
- WDR37 | c.*2G>T | 3'UTR (SNP) | VAF 78/90 reads (87%) | called by muse, mutect2, varscan2
- ZNF107 | c.*1004A>G | 3'UTR (SNP) | VAF 71/266 reads (27%) | called by muse, mutect2, varscan2
- ZNF252P | n.488del | RNA (DEL) | VAF 32/106 reads (30%) | called by mutect2, pindel, varscan2
- ZNF252P | n.245+4690G>T | Intron (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- ZNF276 | c.510-18C>G | Intron (SNP) | VAF 56/105 reads (53%) | called by muse, mutect2, varscan2
